Gene-level copy-number profile of tumor specimen ALCH-B6RG-TTP1-A from ALCHEMIST case ALCH-B6RG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.4 years (27,191 days).
Specimen ALCH-B6RG-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f6316399-8d64-4370-aabb-d27b366845b0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B6RG-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/aa355676-a448-4fe1-ba98-160a7a21326b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 3,104; copy number 2: 54,742; copy number 3: 446; copy number 4: 61; copy number 5: 8; copy number 7: 4; copy number 8: 1; copy number 9: 2.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:62,189,131–62,212,328, 5 genes: PIGPP2, RPS15AP7, L1TD1, AL162739.1, Y_RNA.
- chr2:91,578,478–91,621,421, 3 genes (within-gene range 0–1): AC233266.1, AC233266.2, AC116050.1.
- chr7:98,846,488–98,870,771, 1 gene: TMEM130.
- chr11:70,603,304–70,604,859, 1 gene (within-gene range 0–1): AP001271.2.
- chr13:95,310,830–95,336,201, 2 genes: RNY3P8, RNY4P27.
- chr14:18,395,626–18,419,273, 2 genes: CR383658.2, BNIP3P6.
- chr16:81,106,533–81,106,639, 1 gene (within-gene range 0–2): RNU6-1191P.
- chr16:89,912,119–89,938,761, 4 genes (within-gene range 0–1): MC1R, AC092143.1, AC092143.2, TUBB3.
- chr16:89,969,773–89,972,832, 1 gene (within-gene range 0–1): CENPBD1.
- chr20:31,637,912–31,645,006, 1 gene: COX4I2.
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:234,604,269–234,609,525, 2 genes, copy number 7: IRF2BP2, AL160408.2.
- chr5:135,802,985–135,803,075, 1 gene, copy number 7: MIR5692C1.
- chr6:32,517,353–32,589,848, 4 genes, copy number 5–9: HLA-DRB5, RNU1-61P, HLA-DRB6, HLA-DRB1.
- chr6:32,659,467–32,668,383, 2 genes, copy number 5: HLA-DQB1, HLA-DQB1-AS1.
- chr9:136,401,922–136,439,845, 3 genes, copy number 5–7: ENTR1, PMPCA, INPP5E.
- chr19:859,664–893,218, 2 genes, copy number 5: CFD, MED16.
- chr19:1,238,179–1,239,522, 1 gene, copy number 5: AC004221.1.

Autosomal genes at a single copy (total copy number 1): 972. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
